Gene-level copy-number profile of tumor specimen ALCH-B1U1-TTP1-A from ALCHEMIST case ALCH-B1U1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.7 years (24,013 days).
Specimen ALCH-B1U1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e34d44c3-ed96-4f0e-a395-3aa8f1241e45.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1U1-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/f97d4f4f-996a-46c2-ad84-45ba8e044e42

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 619; copy number 1: 6,506; copy number 2: 50,310; copy number 3: 1,419; copy number 4: 18; copy number 5: 1; copy number 8: 8; copy number 15: 31.

Homozygous deletions (total copy number 0; autosomes only): 84 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:944,203–959,309, 1 gene (within-gene range 0–1): NOC2L.
- chr1:6,579,994–6,614,607, 2 genes (within-gene range 0–2): ZBTB48, KLHL21.
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–1): AL139423.1.
- chr1:20,719,731–20,733,952, 2 genes: SH2D5, AL663074.1.
- chr2:232,343,116–232,351,309, 2 genes (within-gene range 0–2): NRBF2P6, ECEL1P3.
- chr2:241,800,916–241,801,907, 1 gene (within-gene range 0–1): AC131097.1.
- chr7:6,637,318–6,658,279, 1 gene: ZNF316.
- chr7:63,768,257–63,771,047, 1 gene: CICP24.
- chr7:149,776,042–149,833,979, 1 gene: SSPOP.
- chr8:22,042,398–22,164,479, 8 genes: FGF17, DMTN, FAM160B2, NUDT18, HR, REEP4, LGI3, SFTPC.
- chr9:130,892,707–130,939,286, 2 genes (within-gene range 0–2): QRFP, FIBCD1.
- chr11:64,035,970–64,103,653, 2 genes (within-gene range 0–1): AP000721.2, AP006333.2.
- chr12:124,337,181–124,337,242, 1 gene (within-gene range 0–2): MIR6880.
- chr12:131,894,622–131,945,896, 5 genes: ULK1, AC131009.4, AC131009.1, PUS1, AC131009.3.
- chr13:114,107,569–114,108,820, 1 gene (within-gene range 0–2): RASA3-IT1.
- chr15:25,180,497–25,250,940, 39 genes (within-gene range 0–1): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:90,839,641–90,853,608, 1 gene: AC124248.1.
- chr16:89,873,570–89,938,761, 6 genes: TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr17:4,433,940–4,539,035, 4 genes (within-gene range 0–1): SPNS3, AC127521.1, AC118754.1, SPNS2.
- chr18:79,496,058–79,498,348, 1 gene (within-gene range 0–1): AC018445.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 40 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,185,071–55,862,755, 39 genes, copy number 8–15: AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3.
- chr20:62,877,738–62,937,952, 1 gene, copy number 5 (within-gene range 4–5): DIDO1.

Autosomal genes at a single copy (total copy number 1): 4,211. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
